Somatic mutation profile of tumor specimen TCGA-W3-AA1V-06B (aliquot TCGA-W3-AA1V-06B-11D-A401-08) from TCGA case TCGA-W3-AA1V, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 66.4 years (24,260 days).
Specimen TCGA-W3-AA1V-06B: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 857bcee2-eb7e-4981-bc73-8309ca163715.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W3-AA1V-10A (Blood Derived Normal), aliquot TCGA-W3-AA1V-10A-01D-A401-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7a94a0c-ff62-4489-b2c2-bf0e675b268e

The open-access MAF lists 6,513 somatic variants for this specimen: 4,266 protein-altering or splice-affecting, 2,102 silent, 145 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3,872, Silent 2,102, Nonsense Mutation 258, Splice Region 66, Intron 58, RNA 57, Splice Site 37, Frame Shift Del 18, 3'UTR 13, 5'UTR 6, 3'Flank 6, Frame Shift Ins 5.

Variants (750 of 6,513; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP7B | c.1063C>T p.Q355* | Nonsense Mutation (SNP) | VAF 16/54 reads (30%) | catalogued as rs778490238, CM053787, COSV99666306; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 10/14 reads (71%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- F11 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1262002209, CM053239, COSV53005235; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- F8 | c.5878C>T p.R1960* | Nonsense Mutation (SNP) | VAF 40/47 reads (85%) | catalogued as rs137852363, CM860007, COSV64276682; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HCN1 | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1561081319, COSV57492050; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LAMA2 | c.4198C>T p.R1400* | Nonsense Mutation (SNP) | VAF 27/125 reads (22%) | catalogued as rs775112258, CM1311877, COSV70350217; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MMAA | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 20/70 reads (29%) | catalogued as rs1029096863, CM113629, COSV99849569; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYBPC3 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs769167548, COSV99920201; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- NEXMIF | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 32/40 reads (80%) | catalogued as rs878854425, COSV50022161; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.1318C>T p.R440* | Nonsense Mutation (SNP) | VAF 66/127 reads (52%) | hotspot (GDC flag); catalogued as rs778405030, CM950845, COSV62197118; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PALB2 | c.1675C>T p.Q559* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as rs1555461154, COSV99848387; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TACC3 | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 25/69 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.115); catalogued as COSV57603049; called by muse, mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 16/30 reads (53%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV50971746; called by muse, mutect2, varscan2
- A2ML1 | c.4180G>A p.V1394I | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.12); catalogued as COSV100228804; called by muse, mutect2, varscan2
- AADACL2 | c.1124C>T p.S375L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0.029); catalogued as COSV100735750; called by muse, mutect2, varscan2
- ABCA12 | c.6992C>T p.S2331L (on ENST00000272895 / NM_173076.3; = p.S2013L on NM_015657.3) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.779); catalogued as COSV55955292; called by muse, mutect2, varscan2
- ABCA12 | c.2641G>A p.G881R (on ENST00000272895 / NM_173076.3; = p.G563R on NM_015657.3) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.626); catalogued as COSV99789456; called by muse, mutect2, varscan2
- ABCA13 | c.2638G>A p.D880N | Missense Mutation (SNP) | VAF 65/98 reads (66%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV101330013; called by muse, mutect2, varscan2
- ABCA13 | c.7401A>T p.R2467S | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV101446911; called by muse, mutect2, varscan2
- ABCA3 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1011002683, COSV100068321; called by muse, mutect2, varscan2
- ABCA9 | c.458G>A p.R153K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100382983, COSV60624334; called by muse, mutect2, varscan2
- ABCB11 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1272650032, COSV55600918; called by muse, mutect2, varscan2
- ABCB5 | c.1760G>A p.R587Q (on ENST00000404938 / NM_001163941.2; = p.R142Q on NM_178559.6) | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs755832012, COSV51702431; called by muse, mutect2, varscan2
- ABCB6 | c.1982C>T p.S661F | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99202397; called by muse, mutect2, varscan2
- ABCB7 | c.2195A>T p.E732V (on ENST00000373394 / NM_001271696.3; = p.E733V on NM_004299.6) | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV99504222; called by muse, mutect2, varscan2
- ABCB7 | c.2194G>A p.E732K (on ENST00000373394 / NM_001271696.3; = p.E733K on NM_004299.6) | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV99504226; called by muse, mutect2, varscan2
- ABCC11 | c.952G>A p.V318I | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.103); catalogued as COSV62326309; called by muse, mutect2, varscan2
- ABCC12 | c.3861G>A p.M1287I | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60915029; called by muse, mutect2, varscan2
- ABCC4 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.846); catalogued as rs532299842, COSV100972442; called by muse, mutect2, varscan2
- ABCC5 | c.266A>G p.K89R | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.776); catalogued as COSV99656740; called by muse, mutect2
- ABCC6 | c.2683C>T p.P895S | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as COSV52745919; called by muse, mutect2, varscan2
- ABCC8 | c.1981G>T p.G661C | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.377); catalogued as rs750182645, COSV100217068; called by muse, varscan2
- ABCD4 | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV100084118, COSV100084470; called by muse, mutect2
- ABHD6 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV99916990; called by muse, mutect2, varscan2
- ABL2 | c.2903C>T p.S968F (on ENST00000502732 / NM_007314.4; = p.S953F on NM_005158.5) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.365); catalogued as rs774754926, COSV61011263; called by muse, mutect2, varscan2
- ABL2 | c.1534C>T p.P512S (on ENST00000502732 / NM_007314.4; = p.P497S on NM_005158.5) | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.125); catalogued as COSV100772639; called by muse, mutect2, varscan2
- ABLIM1 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 43/197 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV53305860; called by muse, mutect2, varscan2
- AC005833.1 | c.1606C>T p.L536F | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated, low confidence (0.23); catalogued as COSV99362719; called by muse, mutect2, varscan2
- AC024592.3 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.692); catalogued as COSV99398678; called by muse, mutect2, varscan2
- AC097637.1 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs753740098, COSV100564502; called by muse, mutect2, varscan2
- AC126283.2 | c.209A>T p.N70I | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); catalogued as COSV101144348; called by muse, mutect2, varscan2
- AC134980.2 | c.823C>T p.H275Y | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.139); catalogued as COSV100171617; called by mutect2, varscan2
- ACAD10 | c.1966C>T p.P656S | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as COSV100564065; called by muse, mutect2, varscan2
- ACAN | c.6359G>A p.S2120N | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.993); catalogued as COSV100717750; called by muse, mutect2, varscan2
- ACAN | c.7066G>A p.E2356K (on ENST00000560601 / NM_001369268.1; = p.E2280K on NM_001135.3) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as rs758341169, COSV100717752; called by muse, mutect2, varscan2
- ACAP1 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV50134198; called by muse, mutect2, varscan2
- ACD | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.569); catalogued as COSV54667378; called by muse, mutect2
- ACKR1 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100929525; called by muse, mutect2, varscan2
- ACOT4 | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as rs1173729708, COSV58335354; called by muse, mutect2, varscan2
- ACOX3 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV62714016; called by muse, mutect2
- ACOX3 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100711930; called by muse, mutect2
- ACOXL | c.1279G>A p.D427N (on ENST00000389811 / NM_001371254.1; = p.D397N on NM_001142807.4) | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV101094696; called by muse, mutect2, varscan2
- ACP7 | c.1225C>T p.H409Y | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1468163371, COSV100488487; called by muse, mutect2, varscan2
- ACSBG1 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as COSV51907003; called by muse, mutect2, varscan2
- ACSL3 | c.1735C>T p.R579C | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767901557, COSV62483450, COSV62483867; called by muse, mutect2, varscan2
- ACSL5 | c.535G>A p.D179N (on ENST00000354273; = p.D235N on NM_016234.3) | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV100634553; called by muse, mutect2, varscan2
- ACSL6 | c.1171G>C p.E391Q (on ENST00000379240; = p.E416Q on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.248); catalogued as COSV99733369; called by muse, mutect2, varscan2
- ACSM1 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54633037; called by muse, mutect2, varscan2
- ACSM2A | c.1504G>A p.G502R (on ENST00000219054; = p.G423R on NM_001308169.2) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as COSV99525136; called by muse, mutect2, varscan2
- ACSM2B | c.1334G>A p.G445E | Missense Mutation (SNP) | VAF 74/201 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100312524, COSV100312563; called by muse, varscan2
- ACSM3 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 55/99 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV99184320; called by muse, mutect2, varscan2
- ACSM4 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 59/107 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as rs749805632, COSV68069003; called by muse, mutect2, varscan2
- ACSM5 | c.621C>T p.L207= | Splice Region (SNP) | VAF 11/24 reads (46%) | catalogued as COSV59371533; called by muse, mutect2, varscan2
- ACSM5 | c.1532G>A p.G511E | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100088760; called by muse, mutect2, varscan2
- ACSS3 | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs146115032, COSV54101686; called by muse, mutect2, varscan2
- ACSS3 | c.1730C>T p.S577F | Missense Mutation (SNP) | VAF 60/79 reads (76%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV54091558; called by muse, mutect2, varscan2
- ACTL9 | c.745G>C p.D249H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.069); catalogued as rs782509555, COSV100185261; called by muse, mutect2, varscan2
- ACTR3B | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as rs769042294, COSV55449299; called by muse, varscan2
- ACTR3B | c.832G>A p.G278R | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55453438; called by muse, varscan2
- ACTR3B | c.833G>A p.G278E | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99753851; called by muse, varscan2
- ACTR8 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV99213672; called by muse, mutect2, varscan2
- ADA | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100596105; called by muse, mutect2, varscan2
- ADAM12 | c.1140G>A p.M380I | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as COSV100900291; called by muse, mutect2, varscan2
- ADAM18 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV99695354; called by muse, varscan2
- ADAM18 | c.1646G>A p.G549E | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748944460, COSV55858283; called by muse, mutect2, varscan2
- ADAM18 | c.1915T>A p.F639I | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0.096); catalogued as COSV99695358; called by muse, mutect2, varscan2
- ADAM2 | c.190A>C p.N64H | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.722); catalogued as rs1248751167, COSV55861499; called by muse, mutect2, varscan2
- ADAM20 | c.730T>A p.F244I | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV99833394; called by muse, varscan2
- ADAM21 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.445); catalogued as COSV99960852; called by muse, mutect2, varscan2
- ADAM21 | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV50789314, COSV99960855; called by muse, mutect2, varscan2
- ADAM22 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as rs370014529, COSV55969068; called by muse, mutect2, varscan2
- ADAM22 | c.2406G>A p.K802= | Splice Region (SNP) | VAF 23/38 reads (61%) | catalogued as COSV99716472, COSV99717422; called by muse, mutect2, varscan2
- ADAM23 | c.2039C>T p.P680L | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as COSV100007319; called by muse, mutect2, varscan2
- ADAM28 | c.2318C>T p.P773L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs1454811206, COSV56104303; called by muse, mutect2, varscan2
- ADAM29 | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV63660794; called by muse, mutect2, varscan2
- ADAM30 | c.1208G>A p.G403E | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65560749; called by muse, mutect2, varscan2
- ADAM7 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as rs137990671, COSV51537987; called by muse, varscan2
- ADAM7 | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51535001; called by muse, varscan2
- ADAM7 | c.2003-1G>A p.X668_splice | Splice Site (SNP) | VAF 20/65 reads (31%) | catalogued as COSV99443659; called by muse, mutect2, varscan2
- ADAMDEC1 | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as COSV99835997, COSV99836245; called by muse, mutect2, varscan2
- ADAMTS1 | c.2215C>T p.H739Y | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as rs765284680, COSV53168919, COSV99536039; called by muse, mutect2
- ADAMTS10 | c.3253C>T p.Q1085* | Nonsense Mutation (SNP) | VAF 11/16 reads (69%) | catalogued as COSV54352331; called by muse, mutect2, varscan2
- ADAMTS10 | c.1612C>T p.P538S | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.69); catalogued as COSV99546782; called by muse, mutect2, varscan2
- ADAMTS12 | c.2749G>A p.D917N | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100710693; called by muse, mutect2, varscan2
- ADAMTS13 | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | catalogued as COSV100747035; called by muse, mutect2, varscan2
- ADAMTS14 | c.2696G>A p.R899Q | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as rs1473659539, COSV64599865; called by muse, mutect2, varscan2
- ADAMTS18 | c.3487C>T p.H1163Y | Missense Mutation (SNP) | VAF 98/154 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs758636217, COSV99272073; called by muse, mutect2, varscan2
- ADAMTS18 | c.2554C>T p.P852S | Missense Mutation (SNP) | VAF 55/76 reads (72%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as rs774605827, COSV51422948; called by muse, mutect2, varscan2
- ADAMTS18 | c.661G>A p.G221S | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99272077; called by muse, varscan2
- ADAMTS18 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99271760; called by muse, varscan2
- ADAMTS19 | c.2924G>A p.R975Q | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs145234388, COSV50736858; called by muse, mutect2, varscan2
- ADAMTS3 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV99710772; called by muse, mutect2, varscan2
- ADAMTS3 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99710776; called by muse, mutect2, varscan2
- ADAMTS5 | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1335532558, COSV53176221; called by muse, mutect2, varscan2
- ADAMTS9 | c.3691A>G p.K1231E | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99899217; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3215C>T p.S1072F | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.424); catalogued as COSV54451524, COSV99718158; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1663T>C p.F555L | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99647074; called by muse, mutect2, varscan2
- ADCK5 | c.31C>T p.H11Y | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1554857691, COSV100450356; called by muse, mutect2, varscan2
- ADCY7 | c.1504C>T p.H502Y | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs550759370, COSV99575880; called by muse, mutect2, varscan2
- ADCY8 | c.2041G>A p.D681N | Missense Mutation (SNP) | VAF 103/157 reads (66%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.709); catalogued as rs145360233, COSV53913924; called by muse, mutect2, varscan2
- ADCY8 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53923813, COSV99653606; called by muse, mutect2, varscan2
- ADCY9 | c.4003G>A p.E1335K | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.048); catalogued as rs374081146; called by muse, mutect2, varscan2
- ADD2 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV100035346; called by muse, mutect2, varscan2
- ADGRA1 | c.1159G>A p.V387I | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); catalogued as COSV100811015; called by muse, varscan2
- ADGRA1 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1378575511, COSV101192682, COSV66925800; called by muse, mutect2, varscan2
- ADGRA3 | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV99293174; called by muse, mutect2
- ADGRB1 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1028287143, COSV100029512; called by muse, mutect2, varscan2
- ADGRB3 | c.305T>A p.L102* | Nonsense Mutation (SNP) | VAF 36/64 reads (56%) | catalogued as COSV101000314; called by muse, mutect2, varscan2
- ADGRB3 | c.1133G>A p.G378E | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV101000315, COSV65406520; called by muse, mutect2, varscan2
- ADGRB3 | c.2243C>T p.P748L | Missense Mutation (SNP) | VAF 33/42 reads (79%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs766127080, COSV101000316; called by muse, mutect2, varscan2
- ADGRB3 | c.4155G>T p.K1385N | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.046); catalogued as COSV53243163, COSV99484609; called by muse, mutect2, varscan2
- ADGRF2 | c.907G>A p.G303R (on ENST00000296862 / NM_001368115.2; = p.G235R on NM_153839.7) | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.139); catalogued as COSV57290842; called by muse, mutect2, varscan2
- ADGRG4 | c.4096C>T p.P1366S | Missense Mutation (SNP) | VAF 34/44 reads (77%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV54954152; called by muse, mutect2, varscan2
- ADGRG4 | c.6305C>T p.S2102F | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.298); catalogued as COSV99795196; called by muse, mutect2, varscan2
- ADGRL2 | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 43/88 reads (49%) | catalogued as COSV54680746; called by muse, mutect2, varscan2
- ADGRL2 | c.2270C>T p.S757L (on ENST00000370717 / NM_001366005.1; = p.S744L on NM_012302.4) | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99588354; called by muse, mutect2, varscan2
- ADGRL2 | c.3452C>T p.S1151F (on ENST00000370717 / NM_001366005.1; = p.S1138F on NM_012302.4) | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1485370132, COSV54666385; called by muse, mutect2, varscan2
- ADGRL4 | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as rs1213180126, COSV100875852; called by muse, mutect2, varscan2
- ADGRV1 | c.1756C>T p.P586S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.133); catalogued as COSV67979664; called by muse, mutect2, varscan2
- ADGRV1 | c.3028C>T p.R1010C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs748033684, COSV67989189; called by muse, mutect2, varscan2
- ADGRV1 | c.4210G>A p.G1404S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs1440458388, COSV101315755, COSV101316680; called by mutect2, varscan2
- ADGRV1 | c.5786C>T p.A1929V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV101315757; called by muse, mutect2, varscan2
- ADGRV1 | c.6130T>C p.S2044P | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.979); catalogued as COSV101315758; called by muse, mutect2, varscan2
- ADGRV1 | c.6397C>T p.H2133Y | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.105); catalogued as COSV101315759; called by mutect2, varscan2
- ADGRV1 | c.11698G>A p.E3900K | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV67985801, COSV67991956; called by muse, mutect2
- ADGRV1 | c.12982G>A p.E4328K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as rs182452385, COSV67989156; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRV1 | c.14970C>T p.L4990= | Splice Region (SNP) | VAF 6/36 reads (17%) | catalogued as rs368420512, COSV101315762; called by mutect2, varscan2
- ADH1B | c.997G>T p.V333L | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as COSV100520714; called by muse, varscan2
- ADH1B | c.966C>T p.G322= | Splice Region (SNP) | VAF 22/61 reads (36%) | catalogued as rs1368291089, COSV100520716; called by muse, varscan2
- ADH1B | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.407); catalogued as COSV100520717; called by muse, mutect2, varscan2
- ADH1C | c.570C>T p.V190= | Splice Region (SNP) | VAF 22/91 reads (24%) | catalogued as COSV72463482; called by muse, mutect2
- ADHFE1 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.758); catalogued as COSV99397757; called by muse, mutect2
- ADM | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53403491; called by muse, mutect2, varscan2
- ADPRM | c.316C>T p.H106Y | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65754795; called by muse, mutect2, varscan2
- ADRA1B | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100140173; called by muse, mutect2, varscan2
- ADRA2B | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69788277; called by muse, mutect2, varscan2
- ADSS1 | c.659G>A p.R220K | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100272219; called by muse, mutect2, varscan2
- AFG1L | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 58/103 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs765551779, COSV100933927; called by muse, mutect2, varscan2
- AGAP1 | c.1985G>A p.R662Q (on ENST00000304032 / NM_001037131.3; = p.R609Q on NM_014914.5) | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as rs1403878847, COSV58321158; called by muse, mutect2, varscan2
- AGBL1 | c.1621C>T p.P541S | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.169); catalogued as COSV101222723; called by muse, mutect2, varscan2
- AGBL4 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1324232264, COSV100484094; called by muse, mutect2, varscan2
- AGMO | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs765670837, COSV100693990; called by muse, mutect2, varscan2
- AGPAT4 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs1258018983, COSV100211253; called by muse, mutect2, varscan2
- AGPS | c.574C>T p.H192Y | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as COSV99931217; called by muse, mutect2, varscan2
- AGRN | c.2267C>T p.A756V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.029); catalogued as rs1337666477, COSV101038747; called by muse, mutect2, varscan2
- AGRN | c.5017C>T p.P1673S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.028); catalogued as rs775009371, COSV65072243; called by muse, mutect2
- AGRN | c.5018C>T p.P1673L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV101038506, COSV101038755; called by muse, mutect2
- AGXT2 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs930170136, COSV99183734; called by muse, mutect2, varscan2
- AGXT2 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs760978202, COSV51485242; called by muse, mutect2, varscan2
- AHCYL1 | c.1064T>A p.F355Y | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.81); PolyPhen benign (0.354); catalogued as COSV100779558; called by muse, mutect2, varscan2
- AHDC1 | c.4648C>T p.P1550S | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99899156; called by muse, mutect2, varscan2
- AHDC1 | c.1642G>A p.G548S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99899158; called by muse, mutect2, varscan2
- AHNAK | c.3557C>T p.P1186L | Missense Mutation (SNP) | VAF 103/229 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57214974; called by muse, mutect2, varscan2
- AHNAK | c.3556C>T p.P1186S | Missense Mutation (SNP) | VAF 100/228 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV99946897; called by muse, mutect2, varscan2
- AHNAK2 | c.12658C>T p.Q4220* | Nonsense Mutation (SNP) | VAF 62/151 reads (41%) | catalogued as COSV100316965, COSV60927145; called by muse, mutect2, varscan2
- AHNAK2 | c.10445C>T p.S3482F | Missense Mutation (SNP) | VAF 96/271 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs776287598, COSV60920890; called by muse, mutect2, varscan2
- AHNAK2 | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100316969; called by muse, mutect2, varscan2
- AIFM2 | c.706A>T p.T236S | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as COSV100325665; called by muse, mutect2, varscan2
- AIPL1 | c.548G>A p.G183E | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as COSV100006036; called by muse, mutect2, varscan2
- AIRE | c.134A>T p.E45V | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99381084; called by muse, mutect2, varscan2
- AIRE | c.135G>A p.E45= | Splice Region (SNP) | VAF 15/35 reads (43%) | catalogued as COSV99381085; called by muse, mutect2, varscan2
- AJUBA | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs777145914, COSV99400933; called by muse, mutect2, varscan2
- AK4 | c.558G>A p.K186= | Splice Region (SNP) | VAF 7/18 reads (39%) | catalogued as COSV100519852; called by muse, mutect2, varscan2
- AK5 | c.850C>T p.P284S (on ENST00000354567 / NM_174858.3; = p.P258S on NM_012093.4) | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as COSV100642568; called by muse, mutect2, varscan2
- AK7 | c.2043A>C p.R681S | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99967170; called by muse, mutect2, varscan2
- AK9 | c.5035G>A p.E1679K | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV101413957; called by muse, mutect2, varscan2
- AKAP6 | c.5126A>G p.N1709S | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs1482433663, COSV99800040; called by muse, mutect2, varscan2
- AKR1B10 | c.367T>A p.F123I | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV100610172; called by muse, mutect2, varscan2
- ALB | c.454C>T p.H152Y | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as COSV99891220; called by muse, mutect2, varscan2
- ALG10 | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 93/159 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762214045, COSV56791818; called by muse, mutect2, varscan2
- ALG14 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100930842, COSV100930877; called by muse, mutect2, varscan2
- ALG14 | c.350C>A p.S117Y | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100930844; called by muse, mutect2, varscan2
- ALK | c.3328G>A p.E1110K | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as rs1363291878, COSV101201820; called by muse, mutect2, varscan2
- ALK | c.3032G>A p.G1011E | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as COSV101201821, COSV66581990; called by muse, mutect2, varscan2
- ALK | c.2452G>A p.G818R | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777803249, COSV66570604; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALKBH1 | c.529T>C p.Y177H | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.983); catalogued as COSV99380527; called by muse, mutect2, varscan2
- ALMS1 | c.1255G>C p.V419L | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100042062; called by muse, mutect2, varscan2
- ALMS1 | c.3659C>T p.P1220L | Missense Mutation (SNP) | VAF 84/156 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100042064; called by muse, mutect2, varscan2
- ALMS1 | c.8153C>T p.S2718L | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100042065; called by muse, mutect2, varscan2
- ALMS1 | c.8888C>T p.P2963L | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.66); catalogued as COSV52501715; called by muse, mutect2, varscan2
- ALOXE3 | c.1675G>T p.E559* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as COSV100559673; called by muse, mutect2, varscan2
- ALPG | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs764443675, COSV54965427; called by muse, varscan2
- ALPK2 | c.4858G>A p.D1620N | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs977454621, COSV100864291, COSV100864345; called by muse, mutect2, varscan2
- AMBP | c.342G>A p.W114* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV99468983; called by muse, mutect2, varscan2
- AMBRA1 | c.2837C>T p.S946L (on ENST00000458649 / NM_001367468.1; = p.S856L on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs932975059, COSV54062015; called by muse, varscan2
- AMBRA1 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs1426972741, COSV100093517; called by muse, mutect2, varscan2
- AMELX | c.353A>G p.N118S | Missense Mutation (SNP) | VAF 23/27 reads (85%) | SIFT tolerated (0.88); PolyPhen benign (0.062); catalogued as COSV100497771; called by muse, mutect2, varscan2
- AMER3 | c.865C>T p.Q289* | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as COSV100366360; called by muse, mutect2, varscan2
- AMOTL1 | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 52/78 reads (67%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.621); catalogued as COSV100133756; called by muse, mutect2, varscan2
- AMOTL2 | c.1805C>A p.S602Y | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1316925360, COSV51438658, COSV99850619; called by muse, mutect2, varscan2
- AMY1C | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 23/312 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.44); catalogued as COSV100915190, COSV100915201; called by muse, mutect2, varscan2
- AMY2A | c.594G>A p.M198I | Missense Mutation (SNP) | VAF 61/490 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV101340628, COSV70214217; called by muse, mutect2, varscan2
- AMZ2 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV100703142; called by muse, mutect2, varscan2
- ANAPC1 | c.3775C>T p.L1259F | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100594645; called by mutect2, varscan2
- ANAPC5 | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.523); catalogued as COSV99946116; called by muse, mutect2, varscan2
- ANGPTL4 | c.758G>A p.G253D | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100035077; called by muse, mutect2, varscan2
- ANGPTL5 | c.1115T>A p.I372N | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV100527746; called by muse, mutect2, varscan2
- ANGPTL7 | c.273G>A p.M91I | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV100815985; called by muse, mutect2, varscan2
- ANK1 | c.5033G>A p.R1678K | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as COSV55877838; called by muse, mutect2, varscan2
- ANK1 | c.2207G>A p.S736N | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as rs1464367239, COSV99224826; called by muse, mutect2, varscan2
- ANK2 | c.1696C>T p.P566S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100000966; called by muse, varscan2
- ANK2 | c.9463G>A p.D3155N | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); catalogued as COSV100000967; called by muse, mutect2, varscan2
- ANK3 | c.10674A>C p.K3558N | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); catalogued as COSV99779461, COSV99781104; called by muse, mutect2, varscan2
- ANK3 | c.7493C>T p.S2498F | Missense Mutation (SNP) | VAF 74/129 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.191); catalogued as COSV99779464; called by muse, mutect2, varscan2
- ANK3 | c.3846-1G>A p.X1282_splice (on ENST00000280772 / NM_001320874.2; = p.X416_splice on NM_001149.3) | Splice Site (SNP) | VAF 42/61 reads (69%) | catalogued as COSV99779466; called by muse, mutect2, varscan2
- ANK3 | c.1694G>A p.G565E | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867615351, COSV55080279; called by muse, mutect2, varscan2
- ANKAR | c.1040-1G>A p.X347_splice | Splice Site (SNP) | VAF 6/24 reads (25%) | catalogued as COSV99854122; called by muse, mutect2
- ANKEF1 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV101001009, COSV65692338; called by muse, mutect2, varscan2
- ANKEF1 | c.2302C>T p.R768* | Nonsense Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as rs767339625, COSV65691980; called by muse, mutect2, varscan2
- ANKFN1 | c.925T>A p.W309R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100593361; called by muse, mutect2, varscan2
- ANKFN1 | c.1113G>A p.W371* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100593362; called by muse, mutect2, varscan2
- ANKH | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 35/55 reads (64%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV99414870; called by muse, varscan2
- ANKMY1 | c.1960C>T p.P654S | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.278); catalogued as rs1403718770, COSV99801930; called by muse, mutect2, varscan2
- ANKMY1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs145888118; called by muse, mutect2, varscan2
- ANKRA2 | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 27/71 reads (38%) | catalogued as rs150789725; called by muse, mutect2, varscan2
- ANKRD11 | c.3812C>G p.S1271W | Missense Mutation (SNP) | VAF 68/147 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs767520089, COSV56357182; called by muse, mutect2, varscan2
- ANKRD11 | c.3605T>G p.F1202C | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.43); catalogued as COSV99968994; called by muse, mutect2, varscan2
- ANKRD12 | c.3745T>C p.F1249L | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.341); catalogued as rs757719469, COSV100041103; called by muse, mutect2, varscan2
- ANKRD22 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs867928842, COSV100905463; called by muse, mutect2, varscan2
- ANKRD30A | c.565G>A p.E189K (on ENST00000611781; = p.E133K on NM_052997.2) | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100653302; called by muse, mutect2, varscan2
- ANKRD30A | c.964G>A p.E322K (on ENST00000611781; = p.E266K on NM_052997.2) | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT tolerated (0.41); PolyPhen benign (0.292); catalogued as COSV64608757; called by muse, varscan2
- ANKRD30A | c.2546C>T p.P849L (on ENST00000611781; = p.P793L on NM_052997.2) | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV64619834; called by muse, varscan2
- ANKRD30A | c.3769C>T p.Q1257* (on ENST00000611781; = p.Q1201* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | catalogued as COSV100653303; called by muse, mutect2, varscan2
- ANKRD44 | c.2579G>A p.R860K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV99984694; called by muse, mutect2, varscan2
- ANKRD50 | c.3065A>T p.Q1022L | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV101538929; called by muse, mutect2, varscan2
- ANKRD6 | c.181T>A p.L61M | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100329732; called by muse, mutect2
- ANKRD6 | c.2010T>A p.Y670* (on ENST00000339746 / NM_001242809.2; = p.Y665* on NM_014942.4) | Nonsense Mutation (SNP) | VAF 12/45 reads (27%) | catalogued as COSV100329734; called by muse, mutect2, varscan2
- ANKS1B | c.3616G>A p.E1206K (on ENST00000547776 / NM_152788.4; = p.E372K on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV100227706; called by muse, mutect2, varscan2
- ANKS4B | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100289785; called by muse, mutect2, varscan2
- ANLN | c.1198A>G p.I400V | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780364655, COSV99732160; called by muse, mutect2, varscan2
- ANLN | c.1685C>T p.S562L | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs371785488; called by muse, mutect2, varscan2
- ANO1 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.148); catalogued as rs746423412, COSV100303911; called by muse, mutect2, varscan2
- ANO2 | c.412G>A p.D138N (on ENST00000356134 / NM_001278597.3; = p.D142N on NM_001278596.3) | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.217); catalogued as COSV100500187; called by muse, mutect2
- ANO4 | c.2513G>A p.R838Q (on ENST00000392977 / NM_001286615.2; = p.R803Q on NM_178826.4) | Missense Mutation (SNP) | VAF 49/67 reads (73%) | SIFT tolerated (0.24); PolyPhen benign (0.202); catalogued as rs778005685, COSV54596564, COSV54598541; called by muse, mutect2, varscan2
- ANO5 | c.2116C>T p.R706* | Nonsense Mutation (SNP) | VAF 16/65 reads (25%) | catalogued as rs768835530, COSV61082177; called by muse, mutect2, varscan2
- ANO9 | c.1984G>A p.D662N | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.89); catalogued as COSV60385536; called by muse, mutect2, varscan2
- ANP32D | c.17G>A p.W6* | Nonsense Mutation (SNP) | VAF 37/62 reads (60%) | catalogued as COSV99874265; called by muse, mutect2, varscan2
- ANPEP | c.1972C>T p.R658W | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866441038, COSV55594662; called by muse, mutect2, varscan2
- ANXA9 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV64485637; called by muse, mutect2, varscan2
- ANXA9 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs775255778, COSV64484258; called by muse, mutect2, varscan2
- AOAH | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 31/39 reads (79%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.001); catalogued as COSV99332539; called by muse, mutect2, varscan2
- AOC1 | c.1498C>T p.R500C | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs567719730, COSV62868567; called by muse, mutect2, varscan2
- AOX1 | c.3494G>A p.G1165E | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99613570; called by muse, mutect2, varscan2
- AP2A2 | c.2234A>C p.K745T | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100172786; called by muse, mutect2, varscan2
- APBA3 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.04); catalogued as COSV100349637; called by muse, mutect2, varscan2
- APBB1IP | c.841A>T p.K281* | Nonsense Mutation (SNP) | VAF 22/29 reads (76%) | catalogued as COSV100882009; called by muse, mutect2, varscan2
- APBB1IP | c.995T>C p.F332S | Missense Mutation (SNP) | VAF 66/107 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV66136836; called by muse, mutect2, varscan2
- APC2 | c.5300C>T p.S1767F | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs767968941, COSV99279354; called by muse, mutect2, varscan2
- APOB | c.8855G>A p.G2952E | Missense Mutation (SNP) | VAF 62/111 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as COSV99265040; called by muse, mutect2, varscan2
- APOB | c.5834A>C p.D1945A | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99265043; called by muse, mutect2, varscan2
- APOBR | c.2542C>T p.P848S (on ENST00000431282; = p.P857S on NM_018690.4) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV60488725; called by muse, mutect2
- APOC3 | c.181G>A p.G61S | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.38); catalogued as COSV99369231; called by muse, mutect2, varscan2
- APOL1 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV59869052; called by muse, mutect2, varscan2
- APOL1 | c.99G>A p.R33= | Splice Region (SNP) | VAF 10/44 reads (23%) | catalogued as rs752361906, COSV100046030; called by muse, mutect2, varscan2
- APOL5 | c.1128G>A p.G376= | Splice Region (SNP) | VAF 8/51 reads (16%) | catalogued as rs1283815134, COSV99968371; called by muse, mutect2
- AR | c.2756C>T p.T919I | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV101017948; called by muse, mutect2, varscan2
- ARAP1 | c.4148A>G p.E1383G (on ENST00000393609 / NM_001040118.2; = p.E1138G on NM_015242.4) | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as COSV100501788; called by muse, mutect2, varscan2
- ARAP3 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99499574; called by muse, mutect2, varscan2
- AREG | c.410G>A p.R137K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0.028); catalogued as rs1372863094; called by muse, mutect2, varscan2
- ARF1 | c.493G>A p.G165R | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99682987, COSV99683009; called by muse, mutect2, varscan2
- ARFGAP2 | c.1549C>T p.R517C | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as rs11542794, COSV53569913; called by muse, mutect2, varscan2
- ARFGEF1 | c.1355C>T p.S452F | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV99141961; called by muse, mutect2, varscan2
- ARFGEF3 | c.2584C>T p.R862C | Missense Mutation (SNP) | VAF 73/130 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759459619, COSV99292157; called by muse, mutect2, varscan2
- ARHGAP20 | c.793G>A p.G265R | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52814402; called by muse, mutect2, varscan2
- ARHGAP22 | c.1901G>A p.R634Q | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374843400, COSV50932392; called by muse, mutect2, varscan2
- ARHGAP26 | c.2315A>G p.D772G | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.358); catalogued as COSV99190732; called by muse, mutect2, varscan2
- ARHGAP29 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as rs777187517, COSV53112147; called by muse, mutect2, varscan2
- ARHGAP32 | c.2971G>A p.E991K (on ENST00000310343 / NM_001378025.1; = p.E642K on NM_014715.4) | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.054); catalogued as COSV100087514; called by muse, mutect2, varscan2
- ARHGAP32 | c.2735C>T p.S912L (on ENST00000310343 / NM_001378025.1; = p.S563L on NM_014715.4) | Missense Mutation (SNP) | VAF 45/59 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV100087516; called by muse, mutect2, varscan2
- ARHGAP32 | c.1366C>T p.P456S (on ENST00000310343 / NM_001378025.1; = p.P107S on NM_014715.4) | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100087519; called by muse, mutect2, varscan2
- ARHGAP33 | c.3080C>T p.S1027F | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); catalogued as COSV99137931; called by muse, mutect2, varscan2
- ARHGAP39 | c.1080C>G p.N360K | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99430854; called by muse, mutect2, varscan2
- ARHGAP4 | c.2801C>T p.S934F | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs1557101567, COSV100509485; called by muse, mutect2, varscan2
- ARHGAP44 | c.1789C>T p.P597S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99310508; called by muse, mutect2, varscan2
- ARHGAP5 | c.2183C>T p.P728L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0.041); catalogued as COSV61534092; called by muse, mutect2, varscan2
- ARHGAP6 | c.2660C>T p.P887L (on ENST00000337414 / NM_013427.3; = p.P684L on NM_013423.3) | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs888404273, COSV100272698, COSV57297228; called by muse, varscan2
- ARHGAP9 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 44/64 reads (69%) | catalogued as COSV100712397; called by muse, mutect2, varscan2
- ARHGEF17 | c.1895C>T p.S632F | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as COSV99735342; called by muse, mutect2, varscan2
- ARHGEF17 | c.4108C>T p.R1370W | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1231664296, COSV55236385; called by muse, mutect2, varscan2
- ARHGEF28 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99708727; called by muse, mutect2, varscan2
- ARHGEF28 | c.208G>A p.V70I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as COSV99708732; called by muse, mutect2, varscan2
- ARHGEF35 | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated (0.14); PolyPhen benign (0.439); catalogued as COSV100967720; called by muse, varscan2
- ARHGEF40 | c.2954C>T p.P985L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.838); catalogued as rs1197803353, COSV100070244; called by muse, mutect2, varscan2
- ARHGEF5 | c.4099G>A p.E1367K | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV99282734; called by muse, mutect2, varscan2
- ARID5B | c.2465C>T p.S822F | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV99689476; called by muse, mutect2, varscan2
- ARL14 | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759219063, COSV100296463; called by muse, mutect2, varscan2
- ARL5B | c.367T>C p.F123L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as rs1320088519, COSV101040287; called by muse, mutect2, varscan2
- ARMC12 | c.445G>A p.E149K (on ENST00000373866 / NM_001286574.2; = p.E176K on NM_145028.5) | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.719); catalogued as COSV55361484; called by muse, mutect2, varscan2
- ARMC4 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT deleterious (0.05); PolyPhen benign (0.251); catalogued as COSV100536620, COSV59458741; called by muse, mutect2, varscan2
- ARMC5 | c.721C>A p.P241T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as rs1234995998, COSV51654771, COSV99192426; called by muse, mutect2, varscan2
- ARMC5 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs771976948, COSV99192429; called by muse, mutect2, varscan2
- ARMC5 | c.2084C>T p.P695L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.046); catalogued as rs777344006, COSV51660216; called by muse, mutect2, varscan2
- ARMH3 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.892); catalogued as COSV64233374; called by muse, mutect2, varscan2
- ARMS2 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.139); catalogued as COSV101600738; called by muse, mutect2
- ARPC2 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV99826645; called by muse, mutect2, varscan2
- ARPP21 | c.1835C>T p.P612L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as rs746985381, COSV99491681; called by mutect2, varscan2
- ARSA | c.1121C>T p.S374F | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.788); catalogued as COSV53351121; called by muse, mutect2, varscan2
- ARSB | c.793C>T p.H265Y | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99364615; called by muse, mutect2, varscan2
- ARSF | c.1091G>A p.G364E | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100839479; called by muse, mutect2, varscan2
- ARSF | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as COSV63838905, COSV63839268; called by muse, mutect2, varscan2
- ASAH2 | c.1051G>T p.G351* | Nonsense Mutation (SNP) | VAF 27/89 reads (30%) | catalogued as COSV100269881; called by muse, mutect2, varscan2
- ASB15 | c.576C>G p.I192M | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.112); catalogued as COSV51926128, COSV99306417; called by muse, mutect2, varscan2
- ASB15 | c.991G>A p.G331S | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1214826483, COSV99306421, COSV99307011; called by muse, mutect2, varscan2
- ASB15 | c.1659A>T p.K553N | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99306423; called by muse, mutect2, varscan2
- ASB16 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as rs146000947, COSV53233896; called by muse, mutect2, varscan2
- ASCC2 | c.1418C>T p.S473F | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as rs773048728, COSV100316194; called by muse, mutect2, varscan2
- ASF1B | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54616181, COSV99654259; called by muse, mutect2, varscan2
- ASH2L | c.19G>A p.G7R | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs963301432, COSV99166960; called by muse, mutect2
- ASH2L | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1295851732, COSV51702026; called by muse, mutect2, varscan2
- ASIC3 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as rs750380438, COSV52501799; called by muse, mutect2, varscan2
- ASIC4 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV100761649; called by muse, mutect2, varscan2
- ASNS | c.541C>T p.L181F | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.423); catalogued as COSV99446161; called by muse, mutect2, varscan2
- ASPA | c.730C>T p.H244Y | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99559202; called by muse, mutect2, varscan2
- ASPHD1 | c.535C>A p.P179T | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs1409875995, COSV100435328; called by muse, varscan2
- ASPHD1 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1239321295, COSV100435329; called by muse, varscan2
- ASPHD1 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs747965116, COSV100435330; called by muse, varscan2
- ASPM | c.8160T>A p.N2720K | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.119); catalogued as COSV99660101; called by muse, varscan2
- ASPM | c.8050G>A p.D2684N | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.173); catalogued as COSV54129185; called by muse, varscan2
- ASPSCR1 | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.058); catalogued as COSV100142388, COSV100142408; called by muse, mutect2
- ASTN1 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 115/278 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs866639170, COSV56061286; called by muse, mutect2, varscan2
- ASTN1 | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1165870332, COSV56071175; called by muse, mutect2, varscan2
- ASTN1 | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.034); catalogued as rs771416288, COSV99921173; called by muse, mutect2, varscan2
- ASTN2 | c.1165del p.R389Efs*23 | Frame Shift Del (DEL) | VAF 21/38 reads (55%) | catalogued as COSV100524617, COSV100529647; called by pindel, varscan2
- ASXL2 | c.3445C>T p.R1149C | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs377352572, COSV55454592; called by muse, mutect2, varscan2
- ASXL3 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs1461211700, COSV52458522, COSV99324388; called by muse, mutect2, varscan2
- ATF3 | c.514C>T p.Q172* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as COSV99674510; called by muse, mutect2, varscan2
- ATF6B | c.1966C>T p.H656Y | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as COSV64352309; called by muse, mutect2, varscan2
- ATG16L1 | c.869C>T p.S290F (on ENST00000392017 / NM_030803.7; = p.S271F on NM_017974.4) | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV61468129; called by muse, mutect2
- ATG2A | c.1897G>A p.V633I | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.115); catalogued as rs1242760120, COSV101034190; called by muse, mutect2, varscan2
- ATG3 | c.86A>G p.K29R | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.78); PolyPhen benign (0.013); catalogued as rs758683145, COSV99344087; called by muse, mutect2, varscan2
- ATL1 | c.507G>A p.M169I | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as COSV100613019; called by muse, mutect2, varscan2
- ATM | c.3205C>T p.P1069S | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT tolerated (0.45); PolyPhen benign (0.012); catalogued as rs751714261, COSV99589098; called by muse, mutect2, varscan2
- ATOH1 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60037460; called by muse, mutect2, varscan2
- ATP10B | c.3763G>A p.G1255R | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.379); catalogued as rs748791598, COSV59146155; called by muse, mutect2, varscan2
- ATP10D | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754586853, COSV56706682; called by muse, mutect2, varscan2
- ATP13A2 | c.1078G>A p.G360R | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV100454075; called by muse, mutect2, varscan2
- ATP13A4 | c.3365C>T p.S1122F | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs1277356448, COSV100710271; called by muse, mutect2, varscan2
- ATP13A4 | c.2540G>A p.G847D | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100710273; called by muse, mutect2, varscan2
- ATP13A5 | c.2611G>T p.E871* | Nonsense Mutation (SNP) | VAF 22/97 reads (23%) | catalogued as COSV100665020; called by muse, mutect2, varscan2
- ATP1B4 | c.772C>T p.R258C (on ENST00000218008 / NM_001142447.3; = p.R254C on NM_012069.5) | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.53); catalogued as rs149447498, COSV54312900; called by muse, mutect2, varscan2
- ATP2B1 | c.3578G>A p.G1193E | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.17); catalogued as COSV99665477; called by muse, mutect2, varscan2
- ATP2C1 | c.1327C>T p.Q443* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as CM003653, COSV100146597; called by muse, mutect2, varscan2
- ATP4B | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs1056828188, COSV100089692; called by muse, mutect2, varscan2
- ATP5MC3 | c.43C>T p.R15* | Nonsense Mutation (SNP) | VAF 7/48 reads (15%) | catalogued as rs1437202094, COSV99507117; called by muse, mutect2, varscan2
- ATP5MC3 | c.42C>T p.I14= | Splice Region (SNP) | VAF 7/46 reads (15%) | catalogued as COSV99507109, COSV99507118; called by muse, mutect2, varscan2
- ATP6V0A4 | c.420G>A p.T140= | Splice Region (SNP) | VAF 9/53 reads (17%) | catalogued as rs61747679, COSV100022999; called by muse, mutect2
- ATP6V1C1 | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 13/89 reads (15%) | catalogued as rs1280192393, COSV67778068; called by muse, mutect2, varscan2
- ATP6V1C2 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); catalogued as COSV55364498; called by muse, mutect2, varscan2
- ATP8B2 | c.3614A>T p.K1205M (on ENST00000672630; = p.K1172M on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100874485; called by muse, mutect2, varscan2
- ATP9A | c.2284C>T p.P762S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1199748778, COSV100124757, COSV58763661; called by muse, mutect2, varscan2
- ATP9A | c.662C>T p.S221L | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs755462958, COSV58762831; called by muse, varscan2
- ATP9B | c.3070G>A p.G1024S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100303350; called by muse, mutect2, varscan2
- ATRNL1 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV100744032; called by muse, mutect2, varscan2
- ATRX | c.3085C>T p.P1029S | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as COSV100970537; called by muse, mutect2, varscan2
- AXIN1 | c.2008C>T p.L670F | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.051); catalogued as rs1281159388, COSV51993855; called by muse, mutect2, varscan2
- AXL | c.2401G>A p.E801K (on ENST00000301178 / NM_021913.5; = p.E792K on NM_001699.6) | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs745319533, COSV56566991; called by muse, mutect2, varscan2
- B4GALNT2 | c.533G>A p.R178K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as rs200147969, COSV100302520; called by muse, mutect2, varscan2
- B4GALNT2 | c.1373A>C p.Q458P | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.473); catalogued as COSV100302522; called by muse, mutect2, varscan2
- B4GALNT4 | c.285T>A p.F95L | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1458455485, COSV100327416; called by muse, mutect2, varscan2
- BABAM1 | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs765555081, COSV53106564; called by muse, varscan2
- BABAM2 | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 80/170 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59621223; called by muse, mutect2, varscan2
- BAHCC1 | c.2623G>A p.V875I | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV100311484; called by muse, mutect2
- BAHCC1 | c.3721C>T p.P1241S | Missense Mutation (SNP) | VAF 2/9 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.043); catalogued as rs1555654868; called by muse, mutect2
- BAHCC1 | c.3722C>T p.P1241L | Missense Mutation (SNP) | VAF 2/9 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs375132882; called by muse, mutect2
- BAIAP3 | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs370223637; called by muse, mutect2, varscan2
- BANK1 | c.2149-1G>A p.X717_splice | Splice Site (SNP) | VAF 12/28 reads (43%) | catalogued as COSV100536187; called by muse, mutect2, varscan2
- BANP | c.664G>A p.E222K (on ENST00000286122; = p.E191K on NM_017869.4) | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV99621363; called by muse, mutect2, varscan2
- BATF | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54375717; called by muse, mutect2, varscan2
- BBOF1 | c.472C>T p.Q158* | Nonsense Mutation (SNP) | VAF 4/17 reads (24%) | catalogued as COSV101223819; called by muse, mutect2, varscan2
- BBOX1 | c.317G>A p.R106K | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1295859407, COSV99589588; called by muse, mutect2, varscan2
- BBOX1 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as rs1267366394, COSV54192975; called by muse, mutect2, varscan2
- BBS9 | c.2304G>A p.W768* (on ENST00000242067 / NM_001348036.1; = p.W728* on NM_014451.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 20/75 reads (27%) | catalogued as COSV99627475; called by muse, mutect2, varscan2
- BCAS1 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 87/178 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as COSV65085082; called by muse, mutect2, varscan2
- BCL11B | c.1288G>A p.E430K (on ENST00000357195 / NM_001282237.2; = p.E359K on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1208436010, COSV100595140, COSV61733810; called by muse, mutect2, varscan2
- BCL9 | c.176C>T p.S59F | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99324909; called by muse, mutect2, varscan2
- BCL9 | c.4004C>T p.S1335L | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); catalogued as COSV99324911; called by muse, mutect2, varscan2
- BCLAF1 | c.2717A>T p.E906V | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV99219459; called by muse, mutect2, varscan2
- BCLAF3 | c.1186C>T p.L396F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.838); catalogued as rs771826181, COSV100503271; called by muse, mutect2, varscan2
- BDKRB2 | c.508G>A p.G170S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs202134620, COSV100021067; called by muse, mutect2, varscan2
- BDKRB2 | c.509G>A p.G170D | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.348); catalogued as rs1272946587, COSV100021071; called by muse, mutect2, varscan2
- BDP1 | c.4980T>G p.N1660K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100702945; called by muse, mutect2, varscan2
- BEGAIN | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as COSV62067983; called by muse, mutect2, varscan2
- BEND3 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 14/107 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as COSV100944587; called by muse, mutect2, varscan2
- BEND4 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.129); catalogued as COSV101549736; called by muse, mutect2
- BHLHE40 | c.952C>T p.Q318* | Nonsense Mutation (SNP) | VAF 31/58 reads (53%) | catalogued as COSV99848053; called by muse, mutect2, varscan2
- BLID | c.126A>T p.K42N | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.01); catalogued as COSV101601714; called by muse, mutect2, varscan2
- BLNK | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 15/60 reads (25%) | catalogued as COSV56412057; called by muse, mutect2, varscan2
- BLNK | c.40A>G p.K14E | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV99813767; called by muse, mutect2, varscan2
- BMP2 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.103); catalogued as COSV101122076; called by muse, mutect2, varscan2
- BMP3 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV51081577; called by muse, mutect2, varscan2
- BMP3 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.293); catalogued as COSV99261555; called by muse, mutect2, varscan2
- BMP5 | c.436C>T p.H146Y | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as COSV63706898; called by muse, mutect2, varscan2
- BMPER | c.1853G>A p.W618* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV99778802; called by muse, mutect2, varscan2
- BMPR1A | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 44/69 reads (64%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs587782748, COSV100923448, COSV64408049; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BNC1 | c.1384G>A p.D462N | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV100597109; called by muse, mutect2, varscan2
- BNC1 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as rs568405348, COSV61758315; called by muse, mutect2, varscan2
- BNC2 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs1331253127, COSV101032846, COSV66152072; called by muse, mutect2, varscan2
- BNC2 | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 24/56 reads (43%) | catalogued as COSV101032851; called by muse, mutect2, varscan2
- BOD1L1 | c.5465C>T p.S1822L | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as rs771167771, COSV99239039; called by muse, mutect2, varscan2
- BOD1L1 | c.2168C>T p.S723F | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.286); catalogued as COSV99239060; called by muse, mutect2, varscan2
- BPIFA2 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV99487847; called by muse, mutect2, varscan2
- BRAF | c.1520C>T p.S507L (on ENST00000288602 / NM_001374244.1; = p.S467L on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.547); catalogued as rs867748453, COSV56106484; called by muse, mutect2, varscan2
- BRAT1 | c.1483C>A p.P495T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as rs1354679314, COSV100500428, COSV100500748; called by muse, mutect2
- BRCC3 | c.455T>C p.L152P | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557295322, COSV100341561, COSV57462113; called by muse, mutect2, varscan2
- BRD2 | c.1031G>A p.G344E | Missense Mutation (SNP) | VAF 58/78 reads (74%) | SIFT tolerated (1); PolyPhen benign (0.076); catalogued as COSV100875636; called by muse, mutect2, varscan2
- BRF1 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs878910025, COSV100527178; called by muse, mutect2, varscan2
- BRF2 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 56/81 reads (69%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.496); catalogued as rs1219418191, COSV99604852; called by muse, mutect2, varscan2
- BRINP1 | c.1582C>T p.L528F | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV99775138; called by muse, mutect2, varscan2
- BRINP2 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs1199740078, COSV64175114; called by muse, mutect2, varscan2
- BRIP1 | c.983T>C p.F328S | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.124); catalogued as rs876659057, COSV99369857; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRSK2 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as rs1375121848, COSV57543734; called by muse, mutect2, varscan2
- BSN | c.5899G>A p.E1967K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV99608049; called by muse, mutect2, varscan2
- BSN | c.9083C>T p.P3028L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99608057; called by muse, mutect2, varscan2
- BSPRY | c.956G>A p.G319D | Missense Mutation (SNP) | VAF 37/51 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99444886; called by muse, mutect2, varscan2
- BTN3A3 | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV55074007; called by muse, mutect2
- BTNL8 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.031); catalogued as COSV99180458; called by muse, mutect2, varscan2
- BUB1B | c.3130C>T p.P1044S | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as COSV99806798; called by muse, mutect2, varscan2
- BUD31 | c.359G>T p.R120L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV52861652, COSV99463589; called by muse, mutect2, varscan2
- C10orf120 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV100271588; called by muse, mutect2, varscan2
- C10orf120 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV100271590; called by muse, mutect2, varscan2
- C10orf53 | c.296G>C p.R99T | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.018); catalogued as COSV100935036; called by muse, mutect2, varscan2
- C10orf90 | c.1625C>T p.P542L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.563); catalogued as COSV99503643; called by muse, mutect2, varscan2
- C11orf16 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV100393682; called by muse, mutect2, varscan2
- C11orf49 | c.217C>T p.H73Y | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.979); catalogued as COSV53566441, COSV99561961; called by muse, mutect2, varscan2
- C11orf94 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53796665; called by muse, mutect2, varscan2
- C12orf40 | c.1616G>A p.R539K | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1188977866, COSV104410247, COSV61134900, COSV61138477; called by muse, mutect2, varscan2
- C12orf42 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 29/39 reads (74%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.631); catalogued as rs1238971546, COSV100172073; called by muse, mutect2, varscan2
- C12orf50 | c.979C>T p.R327* | Nonsense Mutation (SNP) | VAF 43/63 reads (68%) | catalogued as rs200677856, COSV53893431, COSV53897104; called by muse, mutect2, varscan2
- C12orf66 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); catalogued as COSV100320664; called by muse, mutect2
- C12orf71 | c.758G>A p.R253K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.805); catalogued as COSV70282753; called by muse, mutect2, varscan2
- C16orf78 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV54555026; called by muse, varscan2
- C16orf92 | c.232A>T p.R78W | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99662374; called by muse, mutect2, varscan2
- C19orf33 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 30/37 reads (81%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs1218784912, COSV56650715; called by muse, mutect2, varscan2
- C1QB | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as COSV59245591; called by muse, mutect2, varscan2
- C1QTNF1 | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 16/96 reads (17%) | catalogued as rs1269829167, COSV59261960; called by muse, varscan2
- C1QTNF9B | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV101158563; called by muse, mutect2, varscan2
- C1orf109 | c.524C>G p.P175R | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100787465; called by muse, mutect2, varscan2
- C1orf127 | c.2107C>T p.P703S | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.79); catalogued as COSV100983470; called by muse, mutect2, varscan2
- C1orf162 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV100636198; called by muse, mutect2, varscan2
- C1orf194 | c.476C>T p.S159F (on ENST00000369948 / NM_001245025.3; = p.S147F on NM_001122961.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/65 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100885143; called by muse, mutect2, varscan2
- C1orf210 | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as rs749422678, COSV70682527; called by muse, mutect2, varscan2
- C1orf226 | c.371G>A p.R124K | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as rs761273824, COSV63397169; called by muse, mutect2, varscan2
- C20orf194 | c.2678G>T p.S893I | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99330594; called by muse, mutect2, varscan2
- C22orf31 | c.365G>A p.R122K | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.359); catalogued as COSV99326338; called by muse, mutect2, varscan2
- C22orf42 | c.308-1G>T p.X103_splice | Splice Site (SNP) | VAF 43/93 reads (46%) | catalogued as COSV66076681; called by muse, mutect2, varscan2
- C22orf42 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.193); catalogued as rs770621495, COSV66075330; called by muse, mutect2, varscan2
- C2orf16 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV101284386; called by muse, mutect2, varscan2
- C2orf73 | c.542G>A p.G181D | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.641); catalogued as COSV100471299; called by muse, mutect2
- C2orf78 | c.2141G>A p.G714E | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV101280950; called by muse, mutect2, varscan2
- C2orf78 | c.2453C>T p.S818L | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV101280951; called by muse, mutect2, varscan2
- C3AR1 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50826338, COSV99368404; called by muse, mutect2, varscan2
- C3orf33 | c.711G>A p.W237* (on ENST00000340171 / NM_001308229.2; = p.W194* on NM_173657.2) | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as rs1291002242, COSV100420056; called by muse, mutect2, varscan2
- C3orf38 | c.721C>T p.H241Y | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.345); catalogued as COSV100007378; called by muse, mutect2, varscan2
- C4BPA | c.734C>T p.S245L | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100891193; called by muse, mutect2, varscan2
- C4orf33 | c.460C>T p.Q154* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV99828886; called by muse, mutect2, varscan2
- C5AR2 | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 27/34 reads (79%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV99953715; called by muse, mutect2, varscan2
- C5orf46 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.018); catalogued as rs1168566782, COSV100568401; called by muse, mutect2, varscan2
- C6 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 42/74 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as COSV99666836, COSV99666909; called by muse, mutect2, varscan2
- C6 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.86); PolyPhen benign (0.018); catalogued as rs977192561, COSV99666911; called by muse, mutect2, varscan2
- C6 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as rs201513771, COSV54715726, COSV99666738; called by muse, mutect2, varscan2
- C6orf15 | c.849G>A p.W283* | Nonsense Mutation (SNP) | VAF 25/58 reads (43%) | catalogued as COSV99456800; called by muse, mutect2, varscan2
- C6orf223 | n.119G>A | Splice Region (SNP) | VAF 15/58 reads (26%) | catalogued as COSV100350402; called by muse, mutect2, varscan2
- C7 | c.107G>A p.W36* | Nonsense Mutation (SNP) | VAF 14/35 reads (40%) | catalogued as rs764072783, COSV100495697; called by muse, mutect2, varscan2
- C7 | c.108G>A p.W36* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as COSV100495701; called by muse, mutect2, varscan2
- C7 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV100495703; called by muse, mutect2, varscan2
- C7 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs192679722, COSV57480739; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C7orf33 | c.82C>A p.L28M | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.61); catalogued as COSV100188758; called by muse, mutect2, varscan2
- C8A | c.1393C>T p.H465Y | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs1483234568, COSV63484731; called by muse, varscan2
- C8A | c.1465C>T p.Q489* | Nonsense Mutation (SNP) | VAF 17/85 reads (20%) | catalogued as COSV100776475; called by muse, varscan2
- C8A | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.625); catalogued as COSV63483073; called by muse, varscan2
- C8B | c.1103G>A p.G368E | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV100980751; called by muse, mutect2, varscan2
- C8orf34 | c.1132G>A p.G378R | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57407411; called by muse, mutect2, varscan2
- C9 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as rs867203884, COSV54678843; called by muse, mutect2, varscan2
- C9 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs749534250, COSV54674594; called by muse, mutect2, varscan2
- C9orf43 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV99928291; called by muse, mutect2, varscan2
- C9orf43 | c.1289T>G p.M430R | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs1321442224, COSV99928292; called by muse, mutect2, varscan2
- CABCOCO1 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.802); catalogued as rs1289630799, COSV57595758; called by muse, mutect2
- CABP1 | c.903G>A p.M301I (on ENST00000316803 / NM_001033677.1; = p.M98I on NM_004276.5) | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99974642; called by muse, mutect2, varscan2
- CABP4 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs770541032, COSV56885070; called by muse, mutect2
- CACNA1A | c.2413G>A p.E805K | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.236); catalogued as rs1231997862, COSV64206753; called by muse, mutect2, varscan2
- CACNA1A | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 55/67 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV100801977; called by muse, mutect2, varscan2
- CACNA1C | c.4396C>T p.L1466= | Splice Region (SNP) | VAF 8/28 reads (29%) | catalogued as COSV100217793, COSV59753836; called by muse, mutect2, varscan2
- CACNA1D | c.2103C>T p.I701= (on ENST00000350061 / NM_001128840.3; = p.I721= on NM_000720.4) | Splice Region (SNP) | VAF 41/151 reads (27%) | catalogued as COSV99857600; called by muse, mutect2, varscan2
- CACNA1D | c.2341G>A p.E781K (on ENST00000350061 / NM_001128840.3; = p.E801K on NM_000720.4) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV99857604; called by mutect2, varscan2
- CACNA1D | c.2933C>T p.S978F (on ENST00000350061 / NM_001128840.3; = p.S998F on NM_000720.4) | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV55445565; called by muse, mutect2, varscan2
- CACNA1D | c.3550C>T p.P1184S (on ENST00000350061 / NM_001128840.3; = p.P1204S on NM_000720.4) | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV55468133, COSV99857607; called by muse, mutect2, varscan2
- CACNA1D | c.4996G>A p.E1666K (on ENST00000350061 / NM_001128840.3; = p.E1686K on NM_000720.4) | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as rs758791188, COSV55436370, COSV99860310; called by muse, mutect2, varscan2
- CACNA1E | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62388732; called by muse, mutect2, varscan2
- CACNA1E | c.1996G>A p.G666R | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100702059; called by muse, mutect2, varscan2
- CACNA1E | c.3767C>T p.S1256F | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100702060, COSV100705722; called by muse, varscan2
- CACNA1E | c.4669A>T p.I1557F | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100702064; called by muse, mutect2, varscan2
- CACNA1E | c.4706G>A p.G1569D | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.158); catalogued as COSV100702068; called by muse, varscan2
- CACNA1E | c.5366G>A p.R1789K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.657); catalogued as rs752184993, COSV100702071; called by muse, mutect2, varscan2
- CACNA1G | c.6370C>T p.P2124S | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as rs1192280089, COSV100661662; called by muse, mutect2, varscan2
- CACNA1S | c.1747G>A p.G583R | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100754531, COSV100754902; called by muse, mutect2, varscan2
- CACNA1S | c.1418C>T p.S473F | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV100754903, COSV62944893; called by muse, mutect2, varscan2
- CACNA1S | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.248); catalogued as COSV62936836; called by muse, mutect2, varscan2
- CACNA2D2 | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs887415177, COSV99817416; called by muse, mutect2, varscan2
- CACNA2D3 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 61/101 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777168401, COSV55535703, COSV55590414; called by muse, mutect2, varscan2
- CACNA2D3 | c.2332C>T p.P778S | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.627); catalogued as COSV99872409; called by muse, varscan2
- CACNA2D3 | c.2658G>A p.M886I | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV99872411; called by muse, mutect2, varscan2
- CACNG8 | c.293G>A p.R98K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.066); catalogued as COSV54414517, COSV99554947; called by muse, mutect2, varscan2
- CACTIN | c.1565C>T p.P522L | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.18); PolyPhen benign (0.051); catalogued as rs777249426, COSV99698433; called by muse, mutect2, varscan2
- CACTIN | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as rs933496746, COSV99698435; called by muse, mutect2, varscan2
- CAD | c.3985C>T p.L1329F | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99254881; called by muse, mutect2, varscan2
- CAD | c.5621G>A p.R1874Q | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as rs769172307, COSV99254884; called by mutect2, varscan2
- CADM3 | c.604G>A p.D202N (on ENST00000368125 / NM_001127173.3; = p.D236N on NM_021189.5) | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63683671; called by muse, mutect2, varscan2
- CAGE1 | c.2075A>T p.D692V (on ENST00000512086; = p.D556V on NM_205864.3) | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV99699584; called by muse, mutect2, varscan2
- CALB2 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); catalogued as rs370020807; called by muse, varscan2
- CALCRL | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV101130912; called by muse, varscan2
- CALCRL | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.474); catalogued as COSV101130918; called by muse, mutect2, varscan2
- CALHM1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs140021779; called by muse, mutect2, varscan2
- CAMK1D | c.277C>T p.H93Y | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as COSV101123420; called by muse, mutect2, varscan2
- CAMK2B | c.1674G>A p.A558= | Splice Region (SNP) | VAF 6/12 reads (50%) | catalogued as rs760353023, COSV99322959; called by muse, mutect2, varscan2
- CAMK4 | c.1123G>A p.G375R | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs1451924691, COSV56669879; called by muse, mutect2, varscan2
- CAMK4 | c.1124G>T p.G375V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV56667777, COSV99998868; called by muse, mutect2, varscan2
- CAMKK2 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs771744764, COSV100242832; called by mutect2, varscan2
- CAMKV | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.977); catalogued as COSV99615385; called by muse, mutect2, varscan2
- CAMTA1 | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100348386; called by muse, mutect2, varscan2
- CAMTA1 | c.2096A>T p.E699V | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.261); catalogued as COSV100348391; called by muse, mutect2, varscan2
- CAND2 | c.1490T>C p.M497T (on ENST00000456430 / NM_001162499.2; = p.M404T on NM_012298.3) | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV99928950; called by muse, mutect2, varscan2
- CANX | c.1180C>T p.Q394* | Nonsense Mutation (SNP) | VAF 31/90 reads (34%) | catalogued as COSV99910389; called by muse, mutect2, varscan2
- CAPN10 | c.901T>C p.F301L | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1262758956, COSV99550154; called by muse, mutect2, varscan2
- CAPN11 | c.1825G>A p.G609S | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV101291873; called by muse, mutect2, varscan2
- CAPN11 | c.1826G>A p.G609D | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV101291874; called by muse, mutect2, varscan2
- CAPN12 | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV100185154; called by muse, mutect2, varscan2
- CAPN12 | c.730-1G>A p.X244_splice | Splice Site (SNP) | VAF 45/51 reads (88%) | catalogued as COSV100185157; called by muse, mutect2, varscan2
- CAPN15 | c.1508C>T p.P503L | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54834863; called by muse, mutect2, varscan2
- CAPN2 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs144316024, COSV99689068; called by muse, mutect2, varscan2
- CAPN3 | c.430C>T p.L144F | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1277687577, COSV58822412; called by muse, mutect2, varscan2
- CAPN5 | c.710T>A p.I237N (on ENST00000456580; = p.I197N on NM_004055.5) | Missense Mutation (SNP) | VAF 64/199 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99582022; called by muse, mutect2, varscan2
- CAPN6 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100136819; called by muse, mutect2, varscan2
- CAPRIN1 | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.999); catalogued as rs566066020, COSV100403762; called by muse, mutect2, varscan2
- CAPSL | c.153G>A p.M51I | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV101274240; called by muse, mutect2, varscan2
- CARD10 | c.2117C>T p.P706L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as rs779872538, COSV99324845; called by muse, mutect2, varscan2
- CARD10 | c.1712C>T p.S571F | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.768); catalogued as COSV99324850; called by muse, mutect2, varscan2
- CARD16 | c.575G>A p.G192E | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1565232229, COSV65213284; called by muse, mutect2, varscan2
- CARMIL1 | c.3364C>T p.R1122W | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.591); catalogued as rs568931456, COSV61517161; called by muse, mutect2, varscan2
- CARMIL2 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.706); catalogued as rs948490082, COSV58024112; called by muse, mutect2, varscan2
- CARS1 | c.2057C>T p.P686L | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV99542507; called by muse, varscan2
- CASP10 | c.754G>A p.V252I | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.028); catalogued as COSV53780051; called by muse, mutect2, varscan2
- CASP4 | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.111); catalogued as COSV67744226; called by muse, mutect2, varscan2
- CASS4 | c.1154C>T p.S385F | Missense Mutation (SNP) | VAF 33/53 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV100824628; called by muse, mutect2, varscan2
- CASS4 | c.1493G>A p.R498Q | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs775284457, COSV64385690; called by muse, mutect2, varscan2
- CATSPERB | c.2216G>A p.G739E | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs781701883, COSV99831129; called by muse, mutect2, varscan2
- CATSPERB | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99831130; called by muse, mutect2
- CATSPERB | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1199437029, COSV99831133; called by muse, mutect2
- CATSPERD | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs745670557, COSV58465097; called by muse, mutect2, varscan2
- CATSPERD | c.1902G>A p.M634I | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58464338; called by muse, mutect2, varscan2
- CAVIN2 | c.914G>A p.G305E | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as COSV100414133; called by muse, mutect2, varscan2
- CAVIN2 | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750257572, COSV100414135; called by muse, mutect2, varscan2
- CBL | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 55/77 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779039234, COSV50629608, COSV50630632, COSV50639447; called by muse, mutect2, varscan2
- CBLN2 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 30/37 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99504300; called by muse, mutect2, varscan2
- CBX6 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV99328086; called by muse, mutect2, varscan2
- CCDC102B | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.536); catalogued as COSV100103120; called by muse, mutect2, varscan2
- CCDC105 | c.603G>A p.W201* | Nonsense Mutation (SNP) | VAF 27/31 reads (87%) | catalogued as rs748616183, COSV52965129; called by muse, mutect2, varscan2
- CCDC113 | c.973G>A p.V325I | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs780838577, COSV54685884, COSV54687144; called by muse, mutect2, varscan2
- CCDC14 | c.952C>T p.R318* (on ENST00000488653; = p.R270* on NM_022757.5) | Nonsense Mutation (SNP) | VAF 42/123 reads (34%) | catalogued as rs776294290, COSV59945809; called by muse, mutect2, varscan2
- CCDC141 | c.3613G>A p.E1205K | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV55377357, COSV99836606; called by muse, mutect2, varscan2
- CCDC141 | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as rs1171280128, COSV99836001, COSV99836610; called by muse, mutect2, varscan2
- CCDC144A | c.185G>A p.S62N | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.213); catalogued as COSV100502018; called by muse, mutect2, varscan2
- CCDC146 | c.1525C>T p.R509W | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as rs144226591; called by mutect2, varscan2
- CCDC146 | c.2259G>A p.M753I | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV99592469; called by muse, mutect2, varscan2
- CCDC150 | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as COSV99776784; called by muse, mutect2, varscan2
- CCDC158 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs752261127, COSV66356281; called by muse, mutect2, varscan2
- CCDC158 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1183704781, COSV101187210, COSV66356402; called by muse, mutect2, varscan2
- CCDC170 | c.596A>T p.D199V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV99498340; called by muse, mutect2, varscan2
- CCDC170 | c.1537C>T p.Q513* | Nonsense Mutation (SNP) | VAF 34/58 reads (59%) | catalogued as rs371982631; called by muse, mutect2, varscan2
- CCDC18 | c.1064G>A p.R355K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.89); PolyPhen benign (0.12); catalogued as COSV100159452; called by muse, mutect2, varscan2
- CCDC27 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 42/152 reads (28%) | catalogued as rs760910706, COSV53898240; called by muse, mutect2, varscan2
- CCDC32 | c.454A>C p.T152P | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as rs952793925, COSV100785933; called by muse, mutect2, varscan2
- CCDC40 | c.3355C>T p.P1119S | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777697239, COSV100163120; called by muse, mutect2, varscan2
- CCDC62 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1431683921, COSV99456909; called by muse, mutect2, varscan2
- CCDC68 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as rs761969346, COSV61604542; called by mutect2, varscan2
- CCDC70 | c.567G>A p.M189I | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99665349; called by muse, mutect2, varscan2
- CCDC73 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as rs867778040, COSV100067156; called by muse, mutect2
- CCDC77 | c.1044C>T p.S348= | Splice Region (SNP) | VAF 10/24 reads (42%) | catalogued as COSV99519780; called by muse, mutect2, varscan2
- CCDC83 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1441197726, COSV54700533; called by muse, mutect2, varscan2
- CCDC88A | c.3833C>T p.S1278F | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.786); catalogued as COSV99710226; called by muse, mutect2, varscan2
- CCDC88B | c.1882G>A p.E628K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.039); catalogued as rs1324798826, COSV57268462; called by muse, mutect2, varscan2
- CCDC88C | c.4051A>G p.M1351V | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as COSV101105510; called by muse, mutect2, varscan2
- CCDC9 | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 50/87 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1487967597, COSV99699627; called by muse, mutect2, varscan2
- CCL11 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779946609, COSV100005513; called by mutect2, varscan2
- CCL11 | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.033); catalogued as COSV100005517; called by muse, mutect2, varscan2
- CCL14 | c.80G>A p.R27Q (on ENST00000618404 / NM_032963.4; = p.G43E on NM_032962.4) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.087); catalogued as rs1420519939; called by muse, mutect2, varscan2
- CCL21 | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.026); catalogued as COSV52399050; called by muse, mutect2, varscan2
- CCN5 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV51939169, COSV99509269; called by muse, varscan2
- CCN5 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.046); catalogued as rs780694441, COSV99509270; called by muse, varscan2
- CCP110 | c.130C>T p.L44F | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1342859664, COSV101195252; called by muse, mutect2, varscan2
- CCR2 | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763342847, COSV52748132, COSV99432776; called by muse, mutect2, varscan2
- CCSER1 | c.1610G>T p.R537L | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as rs775741786, COSV100388301, COSV100390100; called by muse, mutect2, varscan2
- CCT8L2 | c.531G>A p.M177I | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV100742676; called by muse, mutect2, varscan2
- CD109 | c.2450C>G p.T817S | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV99753269, COSV99753774; called by muse, mutect2, varscan2
- CD160 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.241); catalogued as COSV99353392; called by muse, mutect2, varscan2
- CD163 | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 13/62 reads (21%) | catalogued as COSV100775797; called by muse, mutect2, varscan2
- CD163L1 | c.3376A>T p.R1126W | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759237188, COSV100549966; called by muse, mutect2, varscan2
- CD163L1 | c.2740G>A p.E914K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1443624008, COSV100549967; called by muse, mutect2, varscan2
- CD163L1 | c.1492G>A p.G498R | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100549968; called by muse, mutect2, varscan2
- CD1A | c.838G>A p.V280M | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs774767602, COSV99192287; called by muse, mutect2, varscan2
- CD1B | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 68/212 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as rs1557823039, COSV63804161, COSV63804598; called by muse, mutect2, varscan2
- CD1C | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.53); catalogued as COSV100939380; called by muse, mutect2, varscan2
- CD1C | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as rs145638725, COSV63805710, COSV63806016; called by muse, mutect2, varscan2
- CD1E | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as rs867813346, COSV63770393; called by muse, mutect2, varscan2
- CD207 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV101338531, COSV101338546; called by muse, varscan2
- CD22 | c.1430G>A p.W477* | Nonsense Mutation (SNP) | VAF 51/65 reads (78%) | catalogued as COSV99323097; called by muse, mutect2, varscan2
- CD300A | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV60409440; called by muse, mutect2, varscan2
- CD300E | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV100151261; called by muse, mutect2, varscan2
- CD300LD | c.163G>A p.G55R | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100032383; called by muse, mutect2, varscan2
- CD33 | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV99220303; called by muse, mutect2, varscan2
- CD3E | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62346795; called by muse, mutect2, varscan2
- CD79B | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.031); catalogued as COSV99137656; called by muse, mutect2, varscan2
- CD86 | c.181G>A p.E61K (on ENST00000330540 / NM_175862.5; = p.E55K on NM_006889.4) | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.031); catalogued as COSV52605248; called by muse, mutect2, varscan2
- CD86 | c.346A>G p.K116E (on ENST00000330540 / NM_175862.5; = p.K110E on NM_006889.4) | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.036); catalogued as COSV100053911; called by muse, mutect2, varscan2
- CD93 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1425826446, COSV55663410; called by mutect2, varscan2
- CDC14A | c.1403C>T p.S468L | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs745785219, COSV60562906; called by muse, mutect2, varscan2
- CDC25C | c.254C>T p.T85I | Missense Mutation (SNP) | VAF 60/110 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs57952536, COSV100086657; called by muse, mutect2, varscan2
- CDC40 | c.679G>A p.G227R | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.029); catalogued as COSV100309241; called by muse, mutect2
- CDC42BPG | c.1442C>T p.P481L | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100712044; called by muse, mutect2, varscan2
- CDCA4 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as COSV100288173; called by muse, mutect2, varscan2
- CDH10 | c.1913G>A p.R638Q | Missense Mutation (SNP) | VAF 60/119 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.532); catalogued as rs1402706331, COSV52570966, COSV52580434; called by muse, mutect2, varscan2
- CDH12 | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 97/202 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66430216; called by muse, mutect2, varscan2
- CDH15 | c.2047G>A p.G683R | Missense Mutation (SNP) | VAF 2/20 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.232); catalogued as COSV57023478; called by muse, mutect2
- CDH18 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV56924251; called by muse, mutect2, varscan2
- CDH23 | c.5542G>A p.D1848N | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs188078418; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH23 | c.5804C>T p.P1935L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV99820307; called by muse, mutect2, varscan2
- CDH23 | c.6320G>A p.R2107Q | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs780094972, COSV56460135; called by muse, varscan2
- CDH23 | c.6337C>T p.Q2113* | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as rs771210121, CM082535, COSV99820309; called by muse, varscan2
- CDH23 | c.9105G>T p.K3035N | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as rs774032276, COSV56485440, COSV99820311; called by muse, mutect2, varscan2
- CDH23 | c.10036G>A p.E3346K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV99820313; called by muse, mutect2
- CDH3 | c.1718C>T p.S573F | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.284); catalogued as COSV99868047; called by muse, mutect2, varscan2
- CDH4 | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs1365879831, COSV100848675; called by muse, mutect2, varscan2
- CDH4 | c.2611G>A p.E871K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200809954, COSV100848676; called by muse, mutect2, varscan2
- CDH5 | c.501G>A p.G167= | Splice Region (SNP) | VAF 13/65 reads (20%) | catalogued as COSV58519790; called by muse, mutect2, varscan2
- CDH6 | c.2336A>T p.D779V | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV99418756; called by muse, mutect2, varscan2
- CDH7 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1394710642, COSV100542020; called by muse, mutect2, varscan2
- CDH7 | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59883340; called by muse, mutect2, varscan2
- CDH8 | c.1573C>T p.P525S | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.859); catalogued as COSV100180896; called by muse, mutect2, varscan2
- CDH8 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs771617779, COSV54865437; called by muse, varscan2
- CDH9 | c.870A>G p.I290M | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs978500051, COSV50362091, COSV99143296; called by muse, mutect2, varscan2
- CDK12 | c.3014C>T p.P1005L | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101420417; called by muse, mutect2, varscan2
- CDK14 | c.427G>A p.E143K (on ENST00000380050 / NM_001287135.2; = p.E125K on NM_012395.3) | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs963889531, COSV99724765; called by muse, mutect2, varscan2
- CDK5 | c.517C>T p.L173F | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99876814; called by muse, mutect2, varscan2
- CDK5RAP1 | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV100212030; called by muse, mutect2, varscan2
- CDRT1 | c.1454G>A p.G485E | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1226637470, COSV63052563; called by muse, mutect2, varscan2
- CECR2 | c.908C>T p.P303L (on ENST00000342247 / NM_001290047.2; = p.P140L on NM_001290046.1) | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as rs374911807; called by muse, mutect2, varscan2
- CELA3A | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs377420172; called by muse, mutect2, varscan2
- CELSR1 | c.4279C>T p.H1427Y | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as rs1023521226, COSV99417817; called by muse, mutect2, varscan2
- CELSR3 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.121); catalogued as COSV99373264; called by muse, mutect2, varscan2
- CENPE | c.5821G>A p.D1941N | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.488); catalogued as rs1458659109, COSV99477601; called by muse, mutect2, varscan2
- CENPO | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 18/65 reads (28%) | catalogued as rs1423006571, COSV99568063; called by muse, mutect2, varscan2
- CENPS-CORT | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as rs771382657, COSV58364242; called by muse, mutect2, varscan2
- CENPT | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.294); catalogued as COSV99534995; called by muse, mutect2, varscan2
- CEP162 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 55/79 reads (70%) | SIFT tolerated (0.6); PolyPhen benign (0.246); catalogued as COSV100002663; called by muse, mutect2, varscan2
- CEP170B | c.914C>T p.P305L (on ENST00000453495; = p.P234L on NM_015005.3) | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV101371473, COSV69024868; called by muse, mutect2
- CEP192 | c.4041T>A p.F1347L | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV100381023; called by muse, mutect2, varscan2
- CEP192 | c.7582C>T p.R2528* | Nonsense Mutation (SNP) | VAF 11/21 reads (52%) | catalogued as rs766305435, COSV58065327; called by muse, mutect2, varscan2
- CEP85L | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 67/96 reads (70%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as COSV62645982; called by muse, mutect2, varscan2
- CERCAM | c.1273G>A p.G425R | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs764208324, COSV65710506; called by muse, mutect2, varscan2
- CERKL | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.113); catalogued as rs762710416, COSV59215463; called by muse, mutect2, varscan2
- CERS6 | c.514C>T p.Q172* | Nonsense Mutation (SNP) | VAF 28/137 reads (20%) | catalogued as rs1222842765, COSV99986877; called by muse, mutect2, varscan2
- CES1 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as rs1468076589, COSV100828628; called by muse, mutect2, varscan2
- CETP | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs750141703, COSV99569979; called by muse, mutect2, varscan2
- CFAP100 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100729154, COSV61504760; called by muse, mutect2, varscan2
- CFAP161 | c.652C>T p.L218F | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.398); catalogued as rs1365181326, COSV99715431; called by muse, mutect2, varscan2
- CFAP221 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV99732296; called by muse, mutect2, varscan2
- CFAP299 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100811535; called by muse, mutect2, varscan2
- CFAP299 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as rs146690045, COSV63872500; called by muse, varscan2
- CFAP43 | c.4114C>T p.H1372Y | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.077); catalogued as COSV100829168; called by muse, mutect2, varscan2
- CFAP43 | c.2475G>A p.M825I | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.376); catalogued as COSV99530608; called by muse, varscan2
- CFAP45 | c.1235A>T p.K412M | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100928549; called by muse, mutect2, varscan2
- CFAP45 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs770746064, COSV63649520; called by muse, mutect2, varscan2
- CFAP47 | c.4846C>T p.P1616S | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100545236; called by muse, mutect2, varscan2
- CFAP52 | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100235045; called by muse, mutect2, varscan2
- CFAP54 | c.7070C>T p.S2357F | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.68); PolyPhen benign (0.294); catalogued as COSV100733093; called by muse, mutect2, varscan2
- CFAP65 | c.4855C>G p.R1619G | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100444982, COSV58557378; called by muse, mutect2, varscan2
- CFAP69 | c.961C>T p.Q321* | Nonsense Mutation (SNP) | VAF 17/62 reads (27%) | catalogued as COSV100289898, COSV100290007; called by muse, mutect2, varscan2
- CFAP91 | c.433T>A p.Y145N | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV99847029; called by muse, mutect2, varscan2
- CFAP92 | c.338T>G p.M113R | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV99414709; called by muse, mutect2, varscan2
- CFH | c.3592G>A p.E1198K | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.069); catalogued as CM060895, CM070672, COSV66407688; called by muse, mutect2, varscan2
- CFHR1 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.074); catalogued as rs368662175; called by muse, mutect2, varscan2
- CFHR4 | c.1592G>A p.G531E (on ENST00000367416 / NM_001201551.2; = p.G285E on NM_006684.5) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.379); catalogued as COSV52224734; called by muse, mutect2, varscan2
- CFHR5 | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99888450; called by muse, mutect2, varscan2
- CFHR5 | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.42); catalogued as COSV99888454; called by muse, mutect2, varscan2
- CFTR | c.386T>A p.L129H | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1162745955, COSV99135270; called by muse, mutect2, varscan2
- CFTR | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 21/84 reads (25%) | catalogued as CM941971, COSV50041069; called by muse, mutect2, varscan2
- CGNL1 | c.684A>T p.K228N | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV99029049, COSV99848013; called by muse, mutect2, varscan2
- CHCHD5 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs199607921; called by muse, mutect2, varscan2
- CHD1L | c.2422C>T p.R808C | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as rs782680914, COSV63612665; called by muse, mutect2, varscan2
- CHD2 | c.1811C>T p.T604I | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as rs764332853, COSV101245090; called by muse, mutect2, varscan2
- CHD3 | c.1601C>T p.P534L | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100391063; called by muse, mutect2, varscan2
- CHD3 | c.3106C>T p.P1036S | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV57878491; called by muse, mutect2, varscan2
- CHD5 | c.5026G>A p.E1676K | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.074); catalogued as COSV99313310; called by muse, mutect2, varscan2
- CHD5 | c.2632C>T p.P878S | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV99313219; called by muse, mutect2, varscan2
- CHD8 | c.6349G>A p.E2117K (on ENST00000646647 / NM_001170629.2; = p.E1838K on NM_020920.4) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as COSV100765277, COSV100765347; called by muse, mutect2, varscan2
- CHD9 | c.7243C>T p.L2415F (on ENST00000398510 / NM_001382353.1; = p.L2399F on NM_025134.7) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.849); catalogued as rs1460955802, COSV99529048; called by muse, mutect2
- CHIA | c.1027G>A p.D343N (on ENST00000343320; = p.D235N on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs972283710, COSV58475092; called by muse, mutect2, varscan2
- CHL1 | c.3446G>A p.R1149Q (on ENST00000397491 / NM_001253387.1; = p.R1165Q on NM_006614.4) | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.31); PolyPhen benign (0.044); catalogued as rs139892128, COSV99852503; called by muse, mutect2, varscan2
- CHRD | c.1262C>T p.T421M | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770711370, COSV99200357; called by muse, varscan2
- CHRM2 | c.931T>A p.S311T | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as COSV57775216; called by muse, mutect2, varscan2
- CHRM2 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.058); catalogued as COSV100281113; called by muse, mutect2, varscan2
- CHRM2 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs1432230108, COSV57765651; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHRM3 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs200014816, COSV99698054; called by muse, mutect2, varscan2
- CHRM5 | c.151G>A p.V51I | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101271906; called by muse, mutect2, varscan2
- CHRNA1 | c.1174G>A p.D392N (on ENST00000261007 / NM_001039523.3; = p.D367N on NM_000079.4) | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.93); catalogued as COSV53683660; called by muse, mutect2, varscan2
- CHRNA4 | c.974T>A p.V325D | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100937400, COSV64720672; called by muse, mutect2, varscan2
- CHRNB1 | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.079); catalogued as rs753126699, COSV99548232; called by muse, mutect2, varscan2
- CHRND | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.9); PolyPhen benign (0.066); catalogued as COSV99285684; called by muse, mutect2, varscan2
- CHRND | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as rs371376389; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHST1 | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV100346177; called by muse, mutect2, varscan2
- CHST10 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99958875; called by muse, mutect2, varscan2
- CHST5 | c.1037G>A p.R346K | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as COSV100291886, COSV60338394; called by muse, varscan2
- CHST5 | c.1031C>T p.S344L | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as rs1458966951, COSV60337256; called by muse, varscan2
- CHSY3 | c.2278C>T p.P760S | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV59277143; called by muse, mutect2, varscan2
- CIB3 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99521768; called by muse, mutect2
- CIITA | c.739G>A p.G247R | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV100161758, COSV60854514; called by muse, mutect2, varscan2
- CIP2A | c.1180C>T p.L394F | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs1331578913, COSV99842784; called by muse, mutect2, varscan2
- CIR1 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100564936; called by muse, mutect2, varscan2
- CKAP2L | c.2072C>T p.S691L | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs376164527; called by muse, mutect2, varscan2
- CKMT1A | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as rs748025746, COSV100787718; called by muse, varscan2
- CLCA4 | c.763C>T p.H255Y | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99760410; called by muse, mutect2
- CLCA4 | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99760411; called by muse, mutect2, varscan2
- CLCN1 | c.2415G>A p.W805* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100577955; called by muse, mutect2
- CLCN2 | c.2303C>T p.P768L | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99658458; called by muse, mutect2, varscan2
- CLCNKB | c.2016+1G>A p.X672_splice | Splice Site (SNP) | VAF 38/126 reads (30%) | catalogued as rs1348712210, COSV65153352; called by muse, mutect2, varscan2
- CLDN10 | c.422A>T p.K141I | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV100176118; called by muse, mutect2, varscan2
- CLDN25 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 57/78 reads (73%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.707); catalogued as COSV101493597; called by muse, mutect2, varscan2
- CLEC10A | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 39/190 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.871); catalogued as COSV99644665; called by muse, mutect2, varscan2
- CLEC16A | c.2975C>T p.S992F | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV99901363; called by muse, mutect2, varscan2
- CLEC1B | c.320G>A p.R107K | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.35); catalogued as rs367744891, COSV53725342; called by muse, mutect2, varscan2
- CLEC4E | c.282T>G p.F94L | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); catalogued as COSV100222588, COSV55226508; called by muse, mutect2, varscan2
- CLEC4E | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100222589; called by muse, mutect2, varscan2
- CLIC6 | c.1987C>T p.P663S (on ENST00000360731 / NM_001317009.2; = p.P645S on NM_053277.3) | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62447366; called by muse, mutect2, varscan2
- CLINT1 | c.1592C>T p.P531L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as rs1338080907, COSV99753828; called by muse, mutect2, varscan2
- CLK4 | c.1132C>T p.Q378* | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | catalogued as COSV100308887; called by muse, mutect2, varscan2
- CLP1 | c.943C>T p.H315Y | Missense Mutation (SNP) | VAF 63/125 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV100239782; called by muse, mutect2, varscan2
- CLPB | c.1636C>T p.R546C | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs748289105, COSV53630036; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLPX | c.1480C>T p.P494S | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100269430; called by muse, mutect2, varscan2
- CLSTN2 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71725811; called by muse, varscan2
5,763 further variants in this file (3,516 protein-altering or splice-affecting, 2,102 silent, 145 other) are not listed here.
